Somatic mutation profile of tumor specimen 0DVDUA from CCDI case PBCMED, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 12.6 years (4,612 days).
Specimen 0DVDUA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f78ae42-9411-40c8-ba19-f8264c07c29c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVDUY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99f2062c-10b6-4305-ba42-01d419c49fd4

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 261/672 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912679, CM080031, COSV55117476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.3233G>A p.R1078H | Missense Mutation (SNP) | VAF 54/671 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs752742612; called by muse, mutect2
- FNDC1 | c.4474C>T p.R1492* | Nonsense Mutation (SNP) | VAF 32/614 reads (5%) | catalogued as rs906444875, COSV51936634; called by muse, mutect2
- MACC1 | c.2192C>T p.A731V | Missense Mutation (SNP) | VAF 214/731 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs752392071; called by muse, mutect2, varscan2
- OR6C4 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 21/736 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.098); called by muse, mutect2
- TMC2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 46/646 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.211); called by muse, mutect2
